PECGS case C083-000020 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction.
https://portal.gdc.cancer.gov/cases/e6cb971d-da13-486a-ab42-a9c8911d82bc

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 57 years; Year of birth: 1965; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 57.2 years (20,892 days); AJCC pathologic stage: Stage IIIA; Progression or recurrence: no.

Other clinical attributes
- Menopause status: Postmenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000020_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000020_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
